Somatic mutation profile of tumor specimen MP2PRT-PAUJZZ-TMP1-A (aliquot MP2PRT-PAUJZZ-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUJZZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,461 days).
Specimen MP2PRT-PAUJZZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7b5da36-56a8-432d-b022-857757dbf038.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJZZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJZZ-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d59e0e79-ee10-4dc4-a901-07c10c279655

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 64/397 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC150 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as rs367670032; called by muse, mutect2, varscan2
- CRY2 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 75/390 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs750109174; called by muse, mutect2, varscan2
- DRD5 | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 80/493 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs376053096; called by muse, mutect2, varscan2
- GATAD1 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 14/552 reads (3%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1261746364, COSV55319491; called by muse, mutect2
- HECW1 | c.4646G>A p.R1549H | Missense Mutation (SNP) | VAF 85/464 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760923794, COSV67842538; called by muse, mutect2, varscan2
- OR9G1 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 15/575 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1239558907; called by muse, mutect2
- PCDHB4 | c.2212G>A p.V738I | Missense Mutation (SNP) | VAF 158/925 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.298); catalogued as COSV52023446; called by muse, mutect2, varscan2
- RYR1 | c.9218G>A p.R3073H | Missense Mutation (SNP) | VAF 81/540 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.902); catalogued as rs767536592; called by muse, varscan2
- ANKRD26 | c.2936G>C p.S979T | Missense Mutation (SNP) | VAF 49/333 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARHGAP28 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 102/673 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- BNC1 | c.771A>G p.I257M | Missense Mutation (SNP) | VAF 80/624 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CDK9 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 97/518 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FER1L6 | c.1692del p.N566Tfs*46 | Frame Shift Del (DEL) | VAF 32/256 reads (13%) | called by mutect2, pindel, varscan2
- MUSK | c.2326del p.Y776Ifs*92 | Frame Shift Del (DEL) | VAF 94/393 reads (24%) | called by mutect2, pindel, varscan2
- SOWAHC | c.179T>G p.V60G | Missense Mutation (SNP) | VAF 161/812 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ADAMTSL3 | c.861C>T p.G287= | Silent (SNP) | VAF 50/329 reads (15%) | catalogued as rs757715678, COSV54451303; called by muse, mutect2, varscan2
- ICE1 | c.867A>G p.G289= | Silent (SNP) | VAF 77/435 reads (18%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2524C>T | Intron (SNP) | VAF 28/253 reads (11%) | called by muse, mutect2, varscan2
